Somatic mutation profile of tumor specimen TARGET-20-PASSYV-03A (aliquot TARGET-20-PASSYV-03A-01D) from TARGET case TARGET-20-PASSYV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.4 years (4,908 days).
Specimen TARGET-20-PASSYV-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d8d0705-a526-4351-b7a2-29e3e4797fe3.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASSYV-14A (Bone Marrow Normal), aliquot TARGET-20-PASSYV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d7451bc5-a00d-4b42-b98e-4a9e9c079e51

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 34/370 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913488, COSV54042116, COSV54042636, COSV54045151; ClinVar: pathogenic; called by muse, mutect2
- FLT3 | c.1775T>C p.V592A | Missense Mutation (SNP) | VAF 20/282 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs1057520025, COSV54051432, COSV54058572, COSV54074139; ClinVar: likely pathogenic; called by muse, mutect2
- FLT3 | c.1471G>T p.V491L | Missense Mutation (SNP) | VAF 74/337 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- SPI1 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 90/175 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
